Surgical pathology report (de-identified scan), TCGA case TCGA-24-2295, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2295-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

*** Converted Case * This report may not match the original report format**

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession

Taken:

Received:

Accessioned:

Reported:

Physician(s):

TCGA - 24 - 2295

DIAGNOSIS:

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA (SEE DESCRIPTION)

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA (SEE DESCRIPTION)

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

OMENTUM, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

SOFT TISSUE; UMBILICAL HERNIA SAC, EXCISION - PAPILLARY SEROUS
ADENOCARCINOMA, METASTATIC

APPENDIX, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

SOFT TISSUE, RIGHT PAROVARIAN, EXCISION - PAPILLARY SEROUS
ADENOCARCINOMA

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA, METASTATIC

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA, METASTATIC

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA, METASTATIC

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY - NO HISTOPATHOLOGIC
ABNORMALITIES

By this signature, I attest that the above diagnosis is based upon my personal
examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Ovary, right, biopsy - "Poorly-differentiated adenocarcinoma" by [REDACTED]

Microscopic Description and Comment:

There is widespread poorly differentiated papillary serous adenocarcinoma in this case. The tumor is concentrated in the right adnexal region, a portion of which was submitted for frozen section. There is considerable involvement of the right fallopian tube which includes circumferential replacement of the mucosa and muscularis with extension through the serosal surface. The normal mucosal epithelium is largely obliterated by this process, but focally, an in-situ component is identified. There is extensive involvement of the peritubal soft tissue. The right ovary is grossly normal in size and configuration. Microscopically, small tumor foci are identified on the ovarian surface and within scattered lymphovascular spaces. There is one confluent nodule of tumor situated in the ovarian hilum and medulla. While it is difficult to be absolutely dogmatic when tumor is as widespread as in this case, the distribution favors a primary in the fallopian tube. Additional foci of tumor are identified on the serosal surface of the uterus where there is minimal involvement of adjacent myometrium. Small foci of tumor are identified on the serosal surface of the left ovary and fallopian tube. There is minimal involvement of the left tubal fimbria. The endometrium is largely atrophic. Scattered clusters of tumor cells are identified in lymphatic spaces within the endometrium, and there are a few larger confluent foci as well. Clusters of tumor cells are identified in myometrial lymphatics as well. There is extensive involvement of the omentum and of the periappendiceal soft tissues. Tumor extend into the outer portions of the appendiceal muscularis and is identified in a few submucosal lymphatics. Metastatic papillary serous adenocarcinoma is also identified in the sample from the umbilical hernia sac. There are no histopathologic abnormalities in the cervix; the squamous epithelium is atrophic. [REDACTED]

History:

The patient is a [REDACTED] with a two-month history of abdominal distension and pain, thought to be inflammatory bowel disease. Abdominopelvic CT revealed 4 cm right adnexal mass, retroperitoneal adenopathy, omental caking, moderate ascites, right cul de sac implant, metastatic lymph node at umbilicus. Ultrasound showed moderate ascites and a 4 cm right adnexal mass. Clinical diagnosis: Ovarian carcinoma. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy and bilateral salpingo-oophorectomy, omentectomy, appendectomy, and umbilical hernia repair.

Specimen(s) Received:

A: FS1-OVARY, RIGHT, BIOPSY
B: X1-OVARY, RIGHT, BIOPSY
C: UMBILICAL HERNIA SAC
D: OMENTUM
E: UTERUS, CERVIX, LSO, CUL-DE-SAC TUMORS
F: PARTIAL RIGHT OVARY
G: APPENDIX

Gross Description:

The specimens are received in seven containers of formalin, each labelled with the patient's name. The first container is labelled "FS" and contains a firm, tan-brown fragment of soft tissue measuring 1.8 x 1.2 x 0.4 cm. It appears to have yellow flecks, throughout parenchyma. [REDACTED]

The second container is labelled "right ovary, X" and contains four brown-tan-white soft tissue, lobulated, focally hemorrhagic and necrotic fragments measuring in aggregate 4 x 4.5 x 2 cm and weighing 17.1 gm. Sectioning shows a firm, tan-white, homogeneous parenchyma. Ovarian parenchyma is not identified. Labelled XA to XE. [REDACTED]

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

15227

The third container is labelled "umbilical hernia sac" and contains a firm, tan-brown-yellow fragment of fibroadipose tissue measuring 3 x 2 x 1 cm in maximum dimensions. Sectioning shows fibrosis and a partially necrotic cavity measuring ~0.7 cm in diameter. [REDACTED]

The fourth container is labelled "uterus, cervix, left salpingo-oophorectomy, cul de sac tumor" and contains a hysterectomy specimen with the left fallopian tube and ovary attached measuring 8 x 6 x 3 cm in maximum dimensions. It weighs 68.1 gm. The anterior serosal surface of the uterus is smooth and tan-brown. Focal nodules measuring ~0.1 to 0.3 cm are noted on the posterior uterine serosal surface. The serosal surfaces of the anterior and posterior cervix are focally roughened, but unremarkable. The ectocervix measures 3 cm and is tan-white, smooth, with focal petechial hemorrhages. The endocervical canal measures 3 x 0.7 x 0.3 cm. It is smooth and grossly unremarkable. The endometrial cavity measures 1.2 x 2.5 x 0.3 cm. The endometrium is tan-brown and appears atrophic and is less than 0.1 mm. Serial sections through the myometrium which is firm and tan-brown show no focal lesions or suspicion for involvement by carcinoma. The left fallopian tube measures 5.5 x 1 cm in maximum dimensions. The fimbriated end is present. A single cyst measuring 0.3 cm in diameter is present on the serosal surface. The cut surface shows a tan-brown mucosa with a lumen identified. The left ovary measures 2 x 1.5 x 1.3 cm. The serosal surface is tan-white and lobulated. The cut surface shows a tan-yellow parenchyma which is firm and edematous and shows no gross involvement by carcinoma. Also present in the container is an intact fragment of the fallopian tube with the fimbriated end and an intact ovary. The specimen measures 6 x 4 x 2.5 cm in maximum dimensions. The serosal surface of the fallopian tube is tan-brown. The fimbriated end shows a polypoid exophytic tan-brown papillary mass measuring 4 x 3.5 x 2.5 cm. This tumor does not involve the proximal and middle portion of the fallopian tube; only the distal and fimbriated end is involved. The ovary measures 2.5 x 2.2 x 1 cm in maximum dimensions. The serosal surface is tan-white and smooth. Cross section shows numerous corpora albicantia. No evidence of tumor is seen grossly. Tumor is present in the adjacent soft tissue. Labelled B1 - anterior cervix; B2 and B3 - anterior endomyometrium; B4 - posterior cervix; B5 and B6 - posterior endomyometrium; B7 - left fallopian tube; B8 and B9 - left ovary; B10 to B17 - right tube and ovary. (Left and right ovaries completely embedded.) [REDACTED]

The fifth container is labelled "partial right ovary" and contains a firm, tan-brown, focally necrotic and hemorrhagic fragment of soft tissue measuring 4.5 x 3.5 x 1 cm. No ovarian parenchyma is identified. Sections show tan-white focally hemorrhagic and necrotic parenchyma. It is grossly suspicious for tumor. [REDACTED]

The sixth container is labelled "appendix" and contains an appendix with mesoappendix attached measuring 7 x 1 x 3 cm in maximum dimensions. The serosal surface of the mesoappendix and the appendix have tan-white nodules that are grossly suspicious for involvement by carcinoma. Sectioning shows a tan-white tumor involving the mesoappendix. The proximal end of the appendix seems to be grossly uninvolved by tumor. [REDACTED] proximal end; D2 to D4 - sections of appendix and mesoappendix. [REDACTED]

The seventh container is labelled "omentum" and contains a fragment of firm, tan-yellow fragment of fibroadipose tissue weighing 346 gm and measuring 16 x 15 x 3 cm in maximum dimensions. There are large areas of tumor involvement grossly. These areas are tan-white, firm, and focally hemorrhagic and necrotic. Representative sections are submitted [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 671bcbca-fea6-4eb6-880d-bab5ac4b9515 (TCGA-24-2295.44D946E9-12AE-437B-9211-1BE42B4D6439.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).